Somatic mutation profile of tumor specimen MP2PRT-PAVHIF-TMP1-A (aliquot MP2PRT-PAVHIF-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVHIF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,160 days).
Specimen MP2PRT-PAVHIF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62dc377d-088f-4d0b-a1a2-7cb55fe2c6df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHIF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHIF-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/643ea314-6b90-440b-9c8c-8b0917fee939

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 12, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAM | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 154/384 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs545087525; called by muse, mutect2, varscan2
- CASP8 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51847282; called by muse, mutect2, varscan2
- CYP4F8 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 153/351 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs764392352, COSV57853968, COSV57855296; called by muse, mutect2, varscan2
- DNAH3 | c.3956C>T p.A1319V | Missense Mutation (SNP) | VAF 161/363 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs376419884; called by muse, mutect2, varscan2
- GPD1 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV56548708; called by muse, mutect2, varscan2
- INSR | c.3213C>G p.F1071L | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100252301; called by muse, mutect2, varscan2
- INSR | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57173643; called by muse, mutect2, varscan2
- MYH11 | c.1127C>G p.T376R | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100258995; called by muse, mutect2, varscan2
- RNF135 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1307575186; called by muse, mutect2, varscan2
- UGT2B7 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1306868807, COSV59442844, COSV59443657; called by muse, mutect2
- ETV6 | c.833_862del p.I278_F287del | In Frame Del (DEL) | VAF 158/258 reads (61%) | called by mutect2, pindel, varscan2
- HNRNPCL2 | c.167_168insTCCA p.Q56Hfs*4 | Frame Shift Ins (INS) | VAF 212/597 reads (36%) | called by mutect2, pindel, varscan2
- NUMA1 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 86/344 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OMA1 | c.1260G>T p.M420I | Missense Mutation (SNP) | VAF 33/453 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- OR1L1 | c.934C>T p.P312S (on ENST00000373686; = p.P262S on NM_001005236.3) | Missense Mutation (SNP) | VAF 97/393 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A10 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- VANGL2 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); called by muse, mutect2
- XRN1 | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF862 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 13/445 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- CD248 | c.1626G>A p.Q542= | Silent (SNP) | VAF 134/525 reads (26%) | catalogued as COSV100256400; called by muse, mutect2, varscan2
- CELA2A | c.360C>T p.N120= | Silent (SNP) | VAF 171/465 reads (37%) | catalogued as rs369588455; called by muse, mutect2, varscan2
- EHBP1L1 | c.3492C>T p.S1164= | Silent (SNP) | VAF 22/700 reads (3%) | called by muse, mutect2
- FER1L5 | c.1356C>T p.P452= (on ENST00000623019; = p.P457= on NM_001293083.2) | Silent (SNP) | VAF 59/226 reads (26%) | catalogued as rs373878629; called by muse, mutect2, varscan2
- KL | c.2748G>A p.S916= | Silent (SNP) | VAF 77/214 reads (36%) | catalogued as rs1367290977, COSV66308316; called by muse, mutect2, varscan2
- KRT85 | c.258C>T p.G86= | Silent (SNP) | VAF 180/745 reads (24%) | catalogued as rs767201385, COSV99225245; called by muse, mutect2, varscan2
- MYOF | c.2899T>C p.L967= | Silent (SNP) | VAF 94/323 reads (29%) | catalogued as rs766673403; called by muse, mutect2, varscan2
- PAX9 | c.648C>T p.P216= | Silent (SNP) | VAF 18/501 reads (4%) | catalogued as COSV100825860; called by muse, mutect2
- PRR5-ARHGAP8 | c.903C>T p.H301= (on ENST00000352766; = p.H178= on NM_181334.5) | Silent (SNP) | VAF 55/523 reads (11%) | catalogued as rs753869236; called by muse, mutect2
- TENM4 | c.579C>T p.H193= | Silent (SNP) | VAF 44/963 reads (5%) | called by muse, mutect2
- UNC13A | c.2328C>T p.S776= | Silent (SNP) | VAF 121/316 reads (38%) | catalogued as rs566710071, COSV53188360, COSV53197127; called by muse, mutect2, varscan2
- USP13 | c.798C>T p.D266= | Silent (SNP) | VAF 22/302 reads (7%) | catalogued as rs531248006; called by muse, mutect2
- IGHV1-69 | chr14:106714683 ins TCTCTCCT | 3'Flank (INS) | VAF 70/198 reads (35%) | called by mutect2, pindel, varscan2
